Somatic mutation profile of tumor specimen 0DRQSY from CCDI case PBCGRW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,564 days).
Specimen 0DRQSY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ee709b8-b18a-4489-9b7d-b06491d1f04b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRQSM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43970a97-4ccd-45cd-9aa1-63225da98b5a

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, In Frame Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP9 | c.1310C>G p.A437G | Missense Mutation (SNP) | VAF 95/186 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as rs1227507303; called by muse, mutect2, varscan2
- KMT2D | c.79A>G p.S27G | Missense Mutation (SNP) | VAF 68/766 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104396926; called by muse, mutect2
- TEX45 | c.1060_1061del p.H355Cfs*71 | Frame Shift Del (DEL) | VAF 78/379 reads (21%) | catalogued as rs1375857443; called by pindel, varscan2
- CD109 | c.2360G>C p.S787T | Missense Mutation (SNP) | VAF 166/743 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- IFT27 | c.353-2A>C p.X118_splice (on ENST00000433985 / NM_001363003.2; = p.X117_splice on NM_006860.5) | Splice Site (SNP) | VAF 48/256 reads (19%) | called by muse, mutect2, varscan2
- KDM2A | c.2788_2793dup p.W930_T931dup | In Frame Ins (INS) | VAF 64/254 reads (25%) | called by mutect2, pindel, varscan2
- SMIM31 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 160/486 reads (33%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- UHMK1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 86/405 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF765 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 227/950 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FLII | c.609G>A p.L203= | Silent (SNP) | VAF 54/274 reads (20%) | catalogued as rs1314363238; called by muse, mutect2, varscan2
- HIRA | c.2817C>A p.L939= | Silent (SNP) | VAF 117/486 reads (24%) | called by muse, mutect2, varscan2
- PXDNL | c.820T>C p.L274= | Silent (SNP) | VAF 119/946 reads (13%) | called by muse, mutect2, varscan2
- SLC12A7 | c.903C>T p.D301= | Silent (SNP) | VAF 72/215 reads (33%) | catalogued as COSV53762293; called by muse, mutect2, varscan2
